Somatic mutation profile of tumor specimen MMRF_1423_1_BM_CD138pos (aliquot MMRF_1423_1_BM_CD138pos_T1_KBS5U_L05377) from MMRF case MMRF_1423, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,040 days).
Specimen MMRF_1423_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 548fc9db-7bfb-4bb4-8b61-d1a0d40f13e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1423_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1423_1_PB_Whole_C3_KBS5U_L05389; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6bd59f4-59c2-4daa-9ab5-f2fb020b509d

The open-access MAF lists 126 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 34, Silent 15, Intron 12, 5'Flank 8, 5'UTR 7, Nonsense Mutation 3, RNA 2, Splice Region 2, 3'Flank 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 147/313 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC12A1 | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 103/156 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555466999; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD36C | c.4334C>T p.T1445M | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.788); catalogued as rs756398168; called by muse, mutect2, varscan2
- ANKS1B | c.2431C>T p.P811S (on ENST00000547776 / NM_152788.4; = p.P37S on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.977); catalogued as rs879387663; called by muse, mutect2, varscan2
- ARMC3 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 73/131 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs200309888, COSV99957797; called by muse, mutect2, varscan2
- AVIL | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 36/72 reads (50%) | catalogued as COSV57683152; called by muse, mutect2, varscan2
- CASP1 | c.623C>T p.A208V (on ENST00000436863 / NM_033292.4; = p.A187V on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/148 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760923024; called by muse, mutect2, varscan2
- FBN2 | c.8524G>A p.D2842N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1282654100; called by muse, mutect2, varscan2
- GRM3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 129/195 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467183, COSV64474717; called by muse, mutect2, varscan2
- H1-4 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56800081, COSV99175236; called by muse, mutect2, varscan2
- IGDCC3 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.677); catalogued as rs1322383051; called by muse, mutect2, varscan2
- IGHV2-70 | c.161G>C p.C54S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs368641348; called by muse, varscan2
- KIAA1217 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775612291, COSV64606789; called by muse, mutect2, varscan2
- KRBA1 | c.2368C>T p.Q790* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | catalogued as rs762106064; called by muse, mutect2, varscan2
- MS4A14 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 60/186 reads (32%) | catalogued as COSV100280639, COSV55733242; called by muse, mutect2, varscan2
- OR13C5 | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101053079; called by muse, mutect2, varscan2
- PMPCA | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs748858881; called by muse, mutect2, varscan2
- PRAMEF19 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1412698391; called by muse, mutect2, varscan2
- RPSA | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1402091973; called by muse, mutect2, varscan2
- SETD2 | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57443873; called by muse, mutect2, varscan2
- SLC9A3R1 | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.044); catalogued as rs938666218; called by muse, mutect2, varscan2
- STAB2 | c.6501G>C p.E2167D | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV101185537; called by muse, mutect2, varscan2
- UTP18 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1276495643; called by muse, mutect2, varscan2
- C17orf75 | c.1091del p.L364* | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- CACNG7 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CSMD3 | c.7636T>C p.F2546L (on ENST00000297405 / NM_001363185.1; = p.F2442L on NM_052900.3) | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CYB5D2 | c.59T>G p.V20G | Missense Mutation (SNP) | VAF 51/52 reads (98%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- E2F6 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ERAL1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- FAM155B | c.1124_1132del p.E375_E377del | In Frame Del (DEL) | VAF 54/90 reads (60%) | called by mutect2, pindel, varscan2
- H3C3 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 69/105 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- KLRC1 | c.588T>C p.H196= | Splice Region (SNP) | VAF 32/34 reads (94%) | called by muse, mutect2, varscan2
- LRP1 | c.10014G>T p.Q3338H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARCHF2 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGT | c.690T>A p.N230K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAWR | c.44G>A p.S15N | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PBX1 | c.827C>G p.T276R | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSENEN | c.38A>C p.N13T | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- ROBO3 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SH3TC1 | c.2915C>T p.A972V | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SOCS1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SRRM2 | c.6491T>A p.I2164K | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- STK38 | c.-5C>T | Splice Region (SNP) | VAF 60/324 reads (19%) | called by muse, mutect2, varscan2
- TOP2B | c.2312C>T p.S771F (on ENST00000264331 / NM_001330700.2; = p.S766F on NM_001068.3) | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- USF3 | c.1479A>C p.Q493H | Missense Mutation (SNP) | VAF 178/258 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- VPS8 | c.3827T>A p.I1276N (on ENST00000625842 / NM_001349294.1; = p.I1274N on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CELSR1 | c.6117G>A p.P2039= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs979569401; called by muse, mutect2, varscan2
- CNTROB | c.1290G>A p.Q430= | Silent (SNP) | VAF 40/41 reads (98%) | catalogued as rs756065380; called by muse, mutect2, varscan2
- FAM71E2 | c.1101G>A p.P367= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as rs1002950252; called by muse, mutect2, varscan2
- H2BC8 | c.297G>A p.V99= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as rs143613920; called by muse, mutect2, varscan2
- H3C11 | c.123C>T p.R41= | Silent (SNP) | VAF 154/239 reads (64%) | catalogued as rs1403438028; called by muse, mutect2, varscan2
- NEMP1 | c.672C>T p.G224= (on ENST00000300128 / NM_001130963.2; = p.G151= on NM_015257.3) | Silent (SNP) | VAF 58/139 reads (42%) | called by muse, mutect2, varscan2
- PLAUR | c.16C>T p.L6= | Silent (SNP) | VAF 59/88 reads (67%) | called by muse, mutect2, varscan2
- PLEKHA8 | c.574C>T p.L192= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs1198705063; called by muse, mutect2, varscan2
- PPP1R37 | c.231C>A p.I77= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- RPS4X | c.153A>G p.R51= | Silent (SNP) | VAF 26/26 reads (100%) | called by muse, mutect2, varscan2
- TAF1B | c.594C>T p.Y198= | Silent (SNP) | VAF 71/150 reads (47%) | called by muse, mutect2, varscan2
- TMEM151B | c.864G>A p.P288= | Silent (SNP) | VAF 82/272 reads (30%) | called by muse, mutect2, varscan2
- UBR4 | c.6411C>T p.S2137= | Silent (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- VEZF1 | c.1032G>A p.Q344= | Silent (SNP) | VAF 41/58 reads (71%) | catalogued as rs774372573; called by muse, mutect2, varscan2
- ZNF208 | c.75G>A p.Q25= | Silent (SNP) | VAF 155/247 reads (63%) | catalogued as COSV68104525; called by muse, mutect2, varscan2
- ABCC1 | c.*32C>T | 3'UTR (SNP) | VAF 44/86 reads (51%) | catalogued as rs1423337432; called by muse, mutect2, varscan2
- ADCY5 | c.*1766G>A | 3'UTR (SNP) | VAF 31/87 reads (36%) | catalogued as rs1396030388; called by muse, mutect2, varscan2
- AFDN | chr6:167825833 C>T | 5'Flank (SNP) | VAF 100/145 reads (69%) | catalogued as rs767079347; called by muse, mutect2, varscan2
- APBB2 | c.*2463G>T | 3'UTR (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- ASB8 | c.235-98C>T | Intron (SNP) | VAF 103/208 reads (50%) | called by muse, mutect2, varscan2
- ATXN7L3B | c.*1952A>G | 3'UTR (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- BATF | c.*228G>A | 3'UTR (SNP) | VAF 84/166 reads (51%) | called by muse, mutect2, varscan2
- BNC2 | c.*895_*898del | 3'UTR (DEL) | VAF 20/70 reads (29%) | catalogued as rs1424617030; called by mutect2, pindel, varscan2
- CD177P1 | n.403C>T | RNA (SNP) | VAF 42/116 reads (36%) | catalogued as rs17856827; called by muse, mutect2, varscan2
- CEP112 | c.*6C>T | 3'UTR (SNP) | VAF 30/149 reads (20%) | catalogued as rs567048300; called by muse, mutect2, varscan2
- CLPTM1 | chr19:44955027 C>T | 5'Flank (SNP) | VAF 57/98 reads (58%) | catalogued as rs781107439; called by muse, mutect2, varscan2
- CNTNAP5 | c.*295T>C | 3'UTR (SNP) | VAF 47/98 reads (48%) | called by muse, mutect2, varscan2
- CPAMD8 | c.2212-56G>T | Intron (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- CUX1 | c.*2420T>G | 3'UTR (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- DARS2 | c.*434T>A | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- DCAF5 | c.-2G>A | 5'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- DCP2 | c.*3609G>T | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- DNAJA2 | c.-101C>T | 5'UTR (SNP) | VAF 26/47 reads (55%) | catalogued as rs1228664625; called by muse, mutect2, varscan2
- DOK4 | c.*431C>T | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- ERLIN2 | c.-15-91C>T | Intron (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- EXOG | chr3:38496311 G>A | 5'Flank (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- FAM172A | c.*343_*358del | 3'UTR (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel, varscan2
- FER | c.*5995G>C | 3'UTR (SNP) | VAF 34/59 reads (58%) | called by muse, mutect2, varscan2
- GAS1 | c.*988T>C | 3'UTR (SNP) | VAF 69/106 reads (65%) | called by muse, mutect2, varscan2
- GSN | c.-37G>A | 5'UTR (SNP) | VAF 17/24 reads (71%) | called by muse, mutect2, varscan2
- H3C10 | c.*8_*13del | 3'UTR (DEL) | VAF 57/231 reads (25%) | called by mutect2, pindel, varscan2
- HECTD1 | c.5674-62C>T | Intron (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- HNRNPM | chr19:8444924 G>A | 5'Flank (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- IKZF1 | c.*1931del | 3'UTR (DEL) | VAF 8/65 reads (12%) | catalogued as rs201790395; called by pindel, varscan2
- KAT14 | chr20:18138127 C>T | 5'Flank (SNP) | VAF 75/150 reads (50%) | called by muse, mutect2, varscan2
- LATS1 | c.2883+233A>G | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- LGR6 | c.*175C>T | 3'UTR (SNP) | VAF 79/164 reads (48%) | called by muse, mutect2, varscan2
- MARCHF3 | c.*1061G>A | 3'UTR (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- MICALL2 | c.2477-16C>T | Intron (SNP) | VAF 49/152 reads (32%) | catalogued as rs776246645, COSV52518633; called by muse, mutect2, varscan2
- MIR1915 | chr10:21494905 C>T | 3'Flank (SNP) | VAF 25/50 reads (50%) | catalogued as rs544270638; called by muse, mutect2, varscan2
- MN1 | c.-878C>T | 5'UTR (SNP) | VAF 63/114 reads (55%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr15:62243628 G>A | 3'Flank (SNP) | VAF 173/249 reads (69%) | called by muse, mutect2, varscan2
- NBPF7 | n.849G>A | RNA (SNP) | VAF 49/92 reads (53%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5347G>A | Intron (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- NTS | c.*359C>T | 3'UTR (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- OGT | c.*1484C>G | 3'UTR (SNP) | VAF 16/18 reads (89%) | called by muse, mutect2, varscan2
- OSBP2 | chr22:30693852 C>T | 5'Flank (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2
- PDIK1L | c.*917A>G | 3'UTR (SNP) | VAF 28/56 reads (50%) | catalogued as rs903427904; called by muse, mutect2, varscan2
- PPM1F | c.*647C>A | 3'UTR (SNP) | VAF 49/103 reads (48%) | called by muse, mutect2, varscan2
- PPM1F | c.355+107C>T | Intron (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- PPM1M | c.*269G>A | 3'UTR (SNP) | VAF 53/152 reads (35%) | catalogued as rs1261210153; called by muse, mutect2, varscan2
- PPP3CA | c.-112C>T | 5'UTR (SNP) | VAF 71/73 reads (97%) | called by muse, mutect2, varscan2
- PRKACB | c.-206C>T | 5'UTR (SNP) | VAF 3/42 reads (7%) | catalogued as rs1557887994, COSV65771414; called by muse, mutect2
- PRRG2 | c.*66C>T | 3'UTR (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- PURB | c.*3991A>G | 3'UTR (SNP) | VAF 11/43 reads (26%) | catalogued as rs944440010; called by muse, mutect2, varscan2
- RFNG | c.662+22C>T | Intron (SNP) | VAF 78/195 reads (40%) | catalogued as rs192120606; called by muse, mutect2, varscan2
- SEC22A | c.-535G>A | 5'UTR (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- SLC12A5 | c.122-5639C>T | Intron (SNP) | VAF 5/55 reads (9%) | catalogued as rs1462463424; called by muse, mutect2, varscan2
- SLC22A8 | c.*360C>T | 3'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- SLC23A2 | c.*3989C>T | 3'UTR (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- SLC7A11 | c.*6517C>T | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- STX2 | c.*226G>A | 3'UTR (SNP) | VAF 73/131 reads (56%) | called by muse, mutect2, varscan2
- TGM7 | c.*8C>A | 3'UTR (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- TMEM107 | c.*727C>A | 3'UTR (SNP) | VAF 45/95 reads (47%) | catalogued as rs541427710; called by muse, mutect2, varscan2
- TMEM184C | c.*1202G>T | 3'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs188156530, COSV56853211; called by muse, mutect2, varscan2
- TUBB8 | chr10:49535 C>T | 5'Flank (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- TUT7 | c.1455+33A>C | Intron (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- VPS35L | chr16:19555615 C>A | 5'Flank (SNP) | VAF 49/90 reads (54%) | catalogued as rs753109676; called by muse, mutect2, varscan2
- ZNF638 | c.2830-20C>T | Intron (SNP) | VAF 8/18 reads (44%) | catalogued as rs1237963627; called by muse, varscan2
- ZSWIM5 | c.*1258G>T | 3'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
